Somatic mutation profile of tumor specimen ALCH-B4YR-TTP1-A (aliquot ALCH-B4YR-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4YR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,935 days).
Specimen ALCH-B4YR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3244f94d-6ad7-446b-b4c2-bdb5af942fac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4YR-NB1-A (Blood Derived Normal), aliquot ALCH-B4YR-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f78ca8d7-2a61-4f6f-b7d0-579dcc925e09

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Nonsense Mutation 3, 3'UTR 1, Frame Shift Del 1, Splice Region 1, 5'UTR 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 65/576 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100651483, COSV60676045; called by muse, mutect2, varscan2
- B4GALNT3 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960733369; called by muse, mutect2
- DLG3 | c.1069C>G p.P357A | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs750262400; called by muse, mutect2, varscan2
- FBXO43 | c.1469_1481del p.M490Nfs*5 | Frame Shift Del (DEL) | VAF 16/192 reads (8%) | catalogued as rs1485107239; called by mutect2, pindel
- HLA-DOA | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs371630344; called by muse, mutect2
- KIF26B | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs369552215; called by muse, mutect2
- KLK6 | c.197+1G>A p.X66_splice | Splice Site (SNP) | VAF 20/304 reads (7%) | catalogued as rs191896325, COSV59566068; called by muse, mutect2
- PARP9 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.091); catalogued as COSV64450713; called by muse, mutect2
- SEC31B | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs375862494; called by muse, mutect2
- TRIM36 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56691125; called by muse, mutect2
- UBE4B | c.1604C>T p.S535F (on ENST00000343090 / NM_001105562.3; = p.S406F on NM_006048.5) | Missense Mutation (SNP) | VAF 43/434 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV53538746; called by muse, mutect2, varscan2
- A2M | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTS3 | c.1856A>G p.Q619R | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.206); called by muse, mutect2
- AFP | c.1743A>C p.K581N | Missense Mutation (SNP) | VAF 24/556 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- C10orf67 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- C12orf66 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2
- CEP131 | c.2629G>C p.E877Q (on ENST00000269392 / NM_001319228.2; = p.E874Q on NM_014984.4) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.79); called by muse, mutect2
- EEF2K | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- GRAMD2A | c.601-8T>G | Splice Region (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- HIPK4 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 68/492 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.10555C>T p.Q3519* | Nonsense Mutation (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- MATN2 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 249/482 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, varscan2
- MMP16 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 100/567 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- OPRL1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.014); called by muse, mutect2
- P4HA1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- RBBP8NL | c.465G>A p.W155* | Nonsense Mutation (SNP) | VAF 313/1231 reads (25%) | called by muse, mutect2, varscan2
- RESF1 | c.3160C>T p.Q1054* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- RPS6KA3 | c.1002A>T p.K334N | Missense Mutation (SNP) | VAF 19/431 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- RTEL1 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 210/697 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A14 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- STMN3 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 228/543 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, varscan2
- USP27X | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2
- ANGEL1 | c.447T>C p.A149= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- APLP1 | c.1821G>A p.K607= (on ENST00000221891 / NM_001024807.3; = p.K606= on NM_005166.4) | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV55706403; called by muse, mutect2
- AQP10 | c.687C>T p.G229= | Silent (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- ELN | c.753C>G p.G251= | Silent (SNP) | VAF 56/564 reads (10%) | catalogued as COSV52710319; called by muse, mutect2
- FLT4 | c.3459C>T p.S1153= | Silent (SNP) | VAF 35/514 reads (7%) | catalogued as rs751835178, COSV56113554; called by muse, mutect2
- KIF21A | c.108A>T p.P36= | Silent (SNP) | VAF 10/287 reads (3%) | called by muse, mutect2
- POF1B | c.648C>A p.I216= | Silent (SNP) | VAF 17/293 reads (6%) | catalogued as COSV99426841; called by muse, mutect2
- POTED | c.1645C>T p.L549= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- PROB1 | c.1893G>A p.V631= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- RSBN1 | c.2088C>T p.A696= | Silent (SNP) | VAF 16/387 reads (4%) | called by muse, mutect2
- SMYD1 | c.405C>T p.H135= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as rs138266399; called by muse, mutect2
- NUBP1 | c.-14G>A | 5'UTR (SNP) | VAF 18/332 reads (5%) | catalogued as rs562628137; called by muse, mutect2
- PTTG1IP | c.169-532G>T | Intron (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- REPIN1 | c.*1G>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
